Surgical pathology report (de-identified scan), TCGA case TCGA-05-4250, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4250-01A (Primary Tumor).

██████:

2. and 3. Resection material from the right lower lobe with a locally advanced, poorly differentiated, adenosquamous carcinoma measuring at least 65 mm, almost complete pleural infiltration and penetration of S6, excision here does not extend into the healthy tissue and in the central direction there are tongue-shaped extensions in the peribronchial, hilar fatty connective tissue with lymph node metastases that show necrotic destruction here. In addition, a multifocal invasion of the blood vessels.

Assessment:

According to these findings, complete removal of the carcinoma is not definite.

Tumor classification:

M-8140/3, G3, pT3, pV1, pN1, pMx, stage III A. R2.

Source: NCI Genomic Data Commons file e6de26e4-01f8-404a-a764-4b8a4a7832fe (TCGA-05-4250.5574F2F8-F247-40E6-A285-7793EDCF5358.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).